Surgical pathology report (de-identified scan), TCGA case TCGA-86-8668, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8668-01A (Primary Tumor).

[page 1 of 3]
	Case ID	Gross Description	Microscopic Description	Diagnosis Details

[page 2 of 3]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 3 x 2.5 x 2 cm Histologic type: Bronchiolo-alveolar carcinoma, mucinous Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Left, lower

ica ID

[page 3 of 3]
Excision date

■■■■■

Excision date

Source: NCI Genomic Data Commons file 0c421333-6f94-443d-908c-437acc8c37dc (TCGA-86-8668.BE6C4CE2-4C88-41A7-BFF6-E5BB157AD3AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).